TCGA case TCGA-2Y-A9HA — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a25a714e-c142-482b-91c8-4fea763e0254

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 36 days.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 70.9 years (25,892 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 3,4 - Fibrous Septa.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radioembolization; Days to treatment start: 0 days; Embolic agent: Other.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 36 days; Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Platelets 153 (unit not recorded by GDC) [Blood test normal range lower: 143; Blood test normal range upper: 382].
- Alpha Fetoprotein 114 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 7].
- Prothrombin Time 10.6 Seconds [Blood test normal range lower: 8.3; Blood test normal range upper: 11.5].
- Albumin 3.5 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.5].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.3].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Hepatitis C Infection; Viral hepatitis serology tests: Hepatitis C Antibody.
- Timepoint category: Initial Diagnosis; Weight: 69 kg; Height: 169 cm; BMI: 24.2.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2Y-A9HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-2Y-A9HA-01A-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 8; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-2Y-A9HA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2Y-A9HA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple; Ishak fibrosis score: 3,4 - Fibrous Speta; New tumor event diagnosis indicator: No.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation, Embolization treatments, Embolization treatment: Embolizing agent utilized: Habib.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 36 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 36 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 36 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2Y-A9HA-01A-11D-A38W-01): tumor purity 0.79, ploidy 1.98, whole-genome doublings 0.
